Gene-level copy-number profile of tumor specimen TCGA-55-8616-01A from TCGA case TCGA-55-8616, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.1 years (21,225 days).
Specimen TCGA-55-8616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.edf5d569-f765-45bd-90c0-d80c9aa80fd7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8616-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98b57583-5adc-4b39-b6bd-4ffaa8e010e8

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,115; copy number 2: 7,506; copy number 3: 10,271; copy number 4: 12,210; copy number 5: 15,203; copy number 6: 7,101; copy number 7: 3,973; copy number 8: 16; copy number 9: 16; copy number 10: 8; copy number 11: 403; copy number 13: 321; copy number 14: 1,644; copy number 21: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8616-01A-11D-2389-01): tumor purity 0.39, ploidy 3.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 2,377 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 11–14 (broad region; genes not listed).
- chr5:53,776,048–55,773,194, 45 genes, copy number 13–21 (within-gene range 5–21): LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, AC016583.2, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO, AC026704.1, DHX29, MTREX, AC020728.1, PLPP1, AC010480.1, MIR5687, RNF138P1, AK4P2, SLC38A9.
- chr5:55,750,206–55,750,401, 1 gene, copy number 13: AC016632.1.
- chr8:40,161,458–145,066,685, 1,621 genes, copy number 14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,115. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
